Surgical pathology report (de-identified scan), TCGA case TCGA-24-1431, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1431-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Service

Location

MRN:

Hospital #

Patient

Accession #

Take [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

TCGA-24-1431

Other Related Clinical Data:

DIAGNOSIS: OMENTUM, BIOPSY

- SEROUS ADENOCARCINOMA, METASTATIC

OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED

FALLOPIAN TUBES, LEFT AND RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- FALLOPIAN TUBES WITH NO HISTOPATHOLOGIC ABNORMALITY

- BILATERAL INVOLVEMENT OF MESOSALPINGEAL TISSUE BY SEROUS ADENOCARCINOMA

SOFT TISSUE, "PELVIC TUMOR," EXCISION

- SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED (SEE COMMENT)

[REDACTED]

Intraoperative Consultation: An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up specimen (omental biopsy) consisting of two fragments of firm, light grey-tan, multinodular tissue, sectioned to reveal uniform light grey-tan fleshy soft tissue. Sampled for frozen section, labeled FS1. Portion of same for Tumor Repository, rest for permanents," [REDACTED]

FS1: Omentum, biopsy [REDACTED]

Source: NCI Genomic Data Commons file 0f0252ec-d5d0-4443-bc88-0a07e98919f3 (TCGA-24-1431.862AA4A2-D399-4AA0-998E-40B331C198CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).